Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7EF, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7EF-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

CC:

....

Clinical Diagnosis & History:

with enlarging left thigh mass. Bx results high grade spindle cell tumor, soft tissue sarcoma.

Specimens Submitted:

- 1: SP: Supra-lateral margin of resection left thigh (fs)
- 2: SP: Left thigh vastus intermedius margin (fs)
- 3: SP: Left thigh distal vastus lateralis margin (fs)
- 4: SP: Left thigh mass

DIAGNOSIS:

- 1) SOFT TISSUE, LEFT THIGH, SUPRA-LATERAL MARGIN; EXCISION:
- SKELETAL MUSCLE AND ADIPOSE TISSUE, NO TUMOR SEEN.
- 2) SOFT TISSUE, LEFT THIGH VASTUS INTERMEDIUS MARGIN; EXCISION:
- SKELETAL MUSCLE, NO TUMOR SEEN.
- 3) SOFT TISSUE, LEFT THIGH DISTAL VASTUS LATERALIS MARGIN; EXCISION:
- SKELETAL MUSCLE, NO TUMOR SEEN.
- 4) SOFT TISSUE, LEFT THIGH; EXCISION:
- MALIGNANT FIBROUS HISTIOCYTOMA WITH GIANT CELL-RICH AREAS, HIGH GRADE, 12.0 CM GREATEST DIMENSION, APPROXIMATELY 10% NECROTIC.
- TUMOR COMES WITHIN 0.025 CM OF THE DESIGNATED POSTEROLATERAL SUPERFICIAL MARGIN (OTHER MARGINS WIDELY FREE).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

** Continued on next page **

CCE ICD-O-3
Sarcoma, pleomorphic cell undifferentiated
880213 880513
Code to highest 880513
path
Histiocytoma fibrous malignant 883013
Site @ Thigh, soft tissue C49.2
JW 9/26/13

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3

1) The specimen is received fresh for frozen section, labeled "Supralateral margin of resection left thigh". It consists of a 1.5 x 1.0 x 0.5 cm, tan, fibrous tissue fragment which is entirely frozen.

Summary of Sections:
FSC - frozen section control

2) The specimen is received fresh for frozen section, labeled "Left thigh vastus intermedius margin". It consists of a 1.5 x 1.0 x 0.6 cm, tan-pink soft tissue fragment. The specimen is entirely frozen.

Summary of Sections:
FSC - frozen section control

3) The specimen is received fresh for frozen section, labeled "Left thigh distal vastus lateralis margin ". It consists of a 1.5 x 1.0 x 0.6 cm, tan-pink soft tissue fragment. The specimen is entirely frozen.

Summary of Sections:
FSC - frozen section control

4) The specimen is received fresh, labeled "Left thigh mass, white stitch marks posterior-lateral superficial margin, green stitch marks deep margin, black stitch marks proximal margin". It consists of a 17.0 x 15.0 x 7.0 cm specimen with 4.0 x 0.6 cm ellipse of skin. The specimen is inked and bisected revealing a 12.0 x 9.0 x 5.5 cm firm gray-white intramuscular mass located 1.5 cm from the proximal margin, 1.5 cm from the distal margin. A pseudocapsule covers the superior margin that is grossly 0.1 cm from the tumor. The mass intramuscular and relatively circumscribed from surrounding tissue. A portion of specimen is given for TPS, and photographs are taken.

Summary of Sections:
DM distal margin
PM proximal margin
PLS - posterior lateral superficial margins
DEEP deep margin
SK skin
MA mass

Summary of Sections:
Part 1: SP: Supra-lateral margin of resection left thigh (fs)

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Block 1 Sect. Site FSC PCs 1 Page 3 of 3

Part 2: SP: Left thigh vastus intermedius margin (fs)

Block 1 Sect. Site FSC PCs 1

Part 3: SP: Left thigh distal vastus lateralis margin (fs)

Block 1 Sect. Site FSC PCs 1

Part 4: SP: Left thigh mass

Block 2 Sect. Site DEEP PCs 2
1 DM 1
8 MA 8
3 PLS 3
1 PM 1
1 SK 1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN SOFT TISSUE.
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: BENIGN SKELETAL MUSCLE.
PERMANENT DIAGNOSIS: SAME
- 3) FROZEN SECTION DIAGNOSIS: BENIGN SKELETAL MUSCLE.
PERMANENT DIAGNOSIS: SAME

** End of Report **

Criteria	W 8/26/13	Yes	No
HPA Discrepancy			✓

Source: NCI Genomic Data Commons file efd55041-845f-4dba-81b6-d4c7590dc969 (TCGA-DX-A7EF.4CE3A144-0B04-4C6E-97C8-C9FD2A671751.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).